Somatic mutation profile of tumor specimen BA2016D (aliquot aq-BA2016D) from BEATAML1.0 case 2167, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.3 years (22,757 days).
Specimen BA2016D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 10d01734-70ac-4a04-83ee-2e08eab40678.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2487D (Solid Tissue Normal), aliquot aq-BA2487D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c135adf2-bf4b-4285-afb2-50aba96397f3

The open-access MAF lists 33 somatic variants for this specimen: 25 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 4, Splice Site 3, Intron 2, 5'Flank 1, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 38/96 reads (40%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- BOD1L1 | c.2391G>C p.R797S | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs1228316103; called by muse, mutect2
- FAM184B | c.842G>C p.R281P | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); catalogued as rs981239837, COSV53951833; called by muse, mutect2, varscan2
- FER | c.2186C>A p.P729Q | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55286928; called by muse, mutect2, varscan2
- GRM1 | c.925G>A p.V309M | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.197); catalogued as rs753190249, COSV51129492; called by mutect2, varscan2
- NGF | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs968846429, COSV101049558, COSV65687627; called by muse, mutect2
- RPS6KA2 | c.1063C>G p.R355G | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.573); catalogued as COSV55822838; called by muse, varscan2
- SCNN1B | c.1006G>C p.A336P | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV56311061; called by muse, mutect2, varscan2
- TAF1C | c.1375G>A p.V459I | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs142225226; called by muse, varscan2
- TBX3 | c.1361G>C p.R454P (on ENST00000257566 / NM_016569.4; = p.R434P on NM_005996.4) | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.301); catalogued as COSV57476668; called by muse, varscan2
- UPF3B | c.1103G>A p.R368Q (on ENST00000276201 / NM_080632.3; = p.R355Q on NM_023010.3) | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.551); catalogued as rs1282813621, CM107802, COSV52231276; called by muse, mutect2, varscan2
- USP29 | c.2485G>T p.V829F | Missense Mutation (SNP) | VAF 59/127 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs746267652, COSV54143961; called by mutect2, varscan2
- ADAL | c.772+1G>C p.X258_splice (on ENST00000562188 / NM_001324366.2; = p.G258A on NM_001012969.4 and 4 other RefSeq transcripts) | Splice Site (SNP) | VAF 6/59 reads (10%) | called by muse, mutect2, varscan2
- ADH1B | c.347+1G>C p.X116_splice | Splice Site (SNP) | VAF 16/91 reads (18%) | called by muse, mutect2, varscan2
- CCDC150 | c.3190-1G>C p.X1064_splice | Splice Site (SNP) | VAF 8/66 reads (12%) | called by muse, mutect2, varscan2
- FCN2 | c.391G>C p.V131L | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FOXP3 | c.254G>T p.R85L | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.605); called by muse, mutect2
- IGHG2 | c.320C>G p.P107R | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- KPNB1 | c.2079G>C p.M693I | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MAGED1 | c.2101G>C p.V701L | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated, low confidence (0.32); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- N6AMT1 | c.248C>G p.A83G | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.869); called by muse, varscan2
- PYGM | c.1677C>G p.N559K | Missense Mutation (SNP) | VAF 55/302 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by mutect2, varscan2
- SLC6A9 | c.408C>G p.G136= (on ENST00000360584 / NM_201649.4; = p.G82= on NM_006934.4 and 2 other RefSeq transcripts) | Splice Region (SNP) | VAF 15/71 reads (21%) | called by muse, mutect2, varscan2
- SYNE2 | c.9936C>G p.D3312E | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF169 | c.1098C>A p.S366R | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- GSTA4 | c.75C>G p.A25= | Silent (SNP) | VAF 27/196 reads (14%) | called by muse, mutect2, varscan2
- LRRC66 | c.990G>C p.T330= | Silent (SNP) | VAF 10/90 reads (11%) | catalogued as COSV58634551; called by muse, mutect2, varscan2
- SAMD4A | c.1023C>G p.A341= | Silent (SNP) | VAF 13/91 reads (14%) | called by muse, mutect2, varscan2
- TMPRSS9 | c.2760G>C p.P920= (on ENST00000648592; = p.P886= on NM_182973.2) | Silent (SNP) | VAF 30/63 reads (48%) | catalogued as rs942625872; called by muse, mutect2, varscan2
- CMC2 | c.81+319C>T | Intron (SNP) | VAF 27/74 reads (36%) | called by muse, mutect2, varscan2
- LILRB3 | c.658+81G>C | Intron (SNP) | VAF 12/95 reads (13%) | called by muse, mutect2
- RCC1 | chr1:28505962 C>G | 5'Flank (SNP) | VAF 4/52 reads (8%) | called by muse, mutect2
- YAF2 | c.-8G>C | 5'UTR (SNP) | VAF 20/40 reads (50%) | called by muse, mutect2, varscan2
